Surgical pathology report (de-identified scan), TCGA case TCGA-G8-6325, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Roswell Park, specimen TCGA-G8-6325-01A (Primary Tumor).

SPECIMENS:

A. PARACAVAL

CGA - G8 - 6325

SPECIMEN(S):

A. PARACAVAL

GROSS DESCRIPTION:

A. PARACAVAL

Received fresh is a pink-tan lymph node measuring 2.5 x 2 x 1cm. The specimen is sectioned and has a uniform pink-tan cut surface. Specimen is handled per lymphoma workup including 5 touch preps, a portion is snap frozen, tissue sent for flow cytometry, B and T-cell gene rearrangement, BCL-2, and B-5 fixed. Majority of sections are submitted as follows:

A1-A8: formalin fixed tissue

A9: B-5 fixed tissue

DIAGNOSIS:

LYMPH NODE AND ADIPOSE TISSUE, PARACAVAL EXCISION:

- HIGHLY PROLIFERATIVE DIFFUSE LARGE B CELL LYMPHOMA,
HISTIOCYTE-RICH. SEE NOTE.

Note: On section A3 immunoassays, the lymphoma is generally strongly positive for CD20, bcl-2 and MUM-1, negative to weakly positive for bcl-6, negative for CD10 and CD30, and with a Ki-67 proliferation index of 60-95%. No definite follicular lymphoma component is seen with CD21. CD30 reacts with <1% cells. CD3 identifies multifocally prominent background T cells. A florid proliferation of reactive histiocytes is also seen.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Lymphadenopathy

Source: NCI Genomic Data Commons file a7d5f276-6f4d-4c6f-ba41-4833eee7685c (TCGA-G8-6325.ADDC26CD-1381-4A9B-882A-E55287F791EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).